Somatic mutation profile of tumor specimen ALCH-B1H9-TTP1-A (aliquot ALCH-B1H9-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1H9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,124 days).
Specimen ALCH-B1H9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaff51bf-7b7d-47ba-9e63-35787f36af5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1H9-NB1-A (Blood Derived Normal), aliquot ALCH-B1H9-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/154eae08-afd0-4a1c-964b-1c6d542d955b

The open-access MAF lists 194 somatic variants for this specimen: 125 protein-altering or splice-affecting, 44 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 44, Intron 11, RNA 7, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 4, 5'Flank 3, 3'UTR 2, Splice Region 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 70/335 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 63/532 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs201799893, CM110176, COSV56683485; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- ABCD1 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 90/349 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1205548762; called by muse, mutect2, varscan2
- AGO1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100940859; called by muse, mutect2, varscan2
- AHRR | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100328188; called by muse, mutect2
- ANK2 | c.3031C>G p.R1011G | Missense Mutation (SNP) | VAF 139/547 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52163529; called by muse, mutect2, varscan2
- ARHGAP32 | c.3053C>G p.P1018R (on ENST00000310343 / NM_001378025.1; = p.P669R on NM_014715.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV59843506; called by muse, mutect2
- ARSI | c.1050G>T p.W350C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749744846, COSV100156004, COSV60817242; called by muse, mutect2, varscan2
- BRINP3 | c.1039A>T p.M347L | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66527147; called by muse, mutect2, varscan2
- COL1A1 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 198/505 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56805827; called by muse, mutect2, varscan2
- CPLANE1 | c.164A>G p.K55R (on ENST00000425232; = p.K127R on NM_023073.3) | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs1450489314; called by mutect2, varscan2
- CPNE7 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as COSV52011139; called by muse, mutect2
- DCAF17 | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs192590459; called by muse, mutect2, varscan2
- ESRRG | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 115/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63170527; called by muse, mutect2, varscan2
- H4C4 | c.179A>T p.K60I | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV61591751; called by muse, mutect2, varscan2
- HAPLN4 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as rs757926614, COSV52268705; called by muse, mutect2
- HSP90AB1 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs1195123707; called by muse, mutect2, varscan2
- IDS | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 100/502 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV61713254; called by muse, mutect2, varscan2
- KCNG3 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs562837515; called by muse, mutect2
- KCNQ4 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as COSV61272339; called by muse, mutect2, varscan2
- KEAP1 | c.1574A>G p.Y525C | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50318396; called by muse, mutect2, varscan2
- KRTAP21-1 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT tolerated, low confidence (0.63); PolyPhen possibly damaging (0.646); catalogued as rs138190567; called by muse, mutect2, varscan2
- LRP1B | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as COSV67254275; called by muse, mutect2
- MC5R | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs147915585; called by muse, mutect2, varscan2
- MEGF8 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.435); catalogued as COSV52075537; called by muse, mutect2, varscan2
- MSL2 | c.1438C>A p.R480S | Missense Mutation (SNP) | VAF 72/464 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV99387522; called by muse, mutect2, varscan2
- MYCBPAP | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765750913; called by muse, mutect2, varscan2
- OR2T11 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100424923; called by muse, mutect2, varscan2
- PCDHA9 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 97/501 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as rs1554142746; called by muse, mutect2, varscan2
- RGS9 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 129/312 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.105); catalogued as COSV52229510; called by muse, mutect2, varscan2
- ROR2 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.911); catalogued as COSV100995974; called by muse, mutect2, varscan2
- SCN3A | c.2932C>T p.L978F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99032329; called by muse, mutect2, varscan2
- SLC2A1 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 63/508 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs796053250; called by muse, mutect2, varscan2
- SLC2A14 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs139157880; called by muse, mutect2, varscan2
- STK11 | c.241A>T p.K81* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as CM062005, COSV58829745; called by muse, mutect2
- SYCP1 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV65699705; called by muse, varscan2
- TIAM1 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | catalogued as rs768372278; called by muse, varscan2
- TOGARAM2 | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 171/740 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101091315; called by muse, mutect2, varscan2
- UNC5C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.921); catalogued as rs781088734, COSV71658271; called by mutect2, varscan2
- UNC79 | c.4789G>T p.V1597L (on ENST00000393151 / NM_001346218.2; = p.V1420L on NM_020818.5) | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV56404882; called by muse, mutect2, varscan2
- ZNF419 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1435009811; called by muse, mutect2
- ZNF496 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV99666056; called by muse, mutect2, varscan2
- ZNF536 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62824767; called by muse, mutect2, varscan2
- ZNF727 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as rs376201644; called by muse, mutect2, varscan2
- ZNF823 | c.1174A>T p.I392L (on ENST00000341191 / NM_001297610.2; = p.I348L on NM_017507.2) | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs1161496070; called by muse, mutect2, varscan2
- ADAMTS5 | c.2329C>A p.L777M | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ANKRD31 | c.4984G>A p.V1662I | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD36C | c.2848dup p.T950Nfs*2 | Frame Shift Ins (INS) | VAF 28/157 reads (18%) | called by pindel, varscan2
- ATP4A | c.2834T>A p.V945D | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- AVPR2 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAIAP3 | c.1062+8G>T | Splice Region (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- BRWD3 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 73/312 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- C12orf4 | c.668A>T p.Y223F | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- C4orf17 | c.118del p.H40Tfs*5 | Frame Shift Del (DEL) | VAF 21/168 reads (13%) | called by mutect2, pindel, varscan2
- CDHR1 | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CDHR1 | c.1613C>A p.A538D | Missense Mutation (SNP) | VAF 154/429 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CENPE | c.3805C>A p.Q1269K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CENPI | c.863T>A p.L288Q | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CLINT1 | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 110/969 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNBD1 | c.566G>A p.W189* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- COL14A1 | c.5162C>G p.S1721* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- COL4A1 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 68/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.2096A>T p.E699V (on ENST00000297405 / NM_001363185.1; = p.E595V on NM_052900.3) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CYP3A43 | c.798+2T>A p.X266_splice | Splice Site (SNP) | VAF 35/133 reads (26%) | called by muse, varscan2
- DDAH2 | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMKN | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 95/272 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DYTN | c.566C>A p.P189Q | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- EPB41L5 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ESRRG | c.282T>G p.S94R | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM20A | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 53/527 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO43 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FLNC | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- FOXD4L4 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); called by mutect2, varscan2
- FTCD | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GATAD2B | c.464A>T p.K155M | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.984); called by muse, mutect2
- GDF3 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPR4 | c.10C>A p.H4N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- KANK4 | c.449T>A p.L150H | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- KCNQ2 | c.2094G>C p.Q698H (on ENST00000359125 / NM_172107.4; = p.Q670H on NM_004518.6) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIF1B | c.1315C>G p.L439V (on ENST00000377086 / NM_001365952.1; = p.L393V on NM_015074.3) | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.017); called by muse, mutect2
- LARS1 | c.779G>T p.G260V (on ENST00000394434 / NM_020117.11; = p.G233V on NM_016460.3) | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, varscan2
- LCK | c.406del p.D136Tfs*43 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- LTBP1 | c.5010C>A p.N1670K (on ENST00000404816 / NM_206943.4; = p.N1344K on NM_000627.4) | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MAGEB6B | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- MAGEL2 | c.3593del p.L1198Rfs*127 | Frame Shift Del (DEL) | VAF 44/184 reads (24%) | called by mutect2, pindel*, varscan2
- MAOA | c.684del p.E228Dfs*3 | Frame Shift Del (DEL) | VAF 48/452 reads (11%) | called by mutect2, varscan2
- MDGA1 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 89/511 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MED4 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPP1 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYB | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- NBAS | c.2525T>C p.V842A | Missense Mutation (SNP) | VAF 121/513 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NYAP2 | c.1844G>T p.C615F | Missense Mutation (SNP) | VAF 69/362 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR11H12 | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.43); called by mutect2, varscan2
- OR2AJ1 | c.664A>C p.I222L | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51B2 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PKN3 | c.1397G>T p.S466I | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); called by muse, varscan2
- PSME4 | c.702_706del p.W234* | Nonsense Mutation (DEL) | VAF 20/113 reads (18%) | called by mutect2, pindel, varscan2
- PTPN20CP | n.616G>A | Splice Region (SNP) | VAF 35/193 reads (18%) | called by muse, mutect2, varscan2
- R3HDM1 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 68/337 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RAP1GDS1 | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- RBM12 | c.1216C>G p.Q406E | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SAGE1 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2
- SLC35F4 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC8A1 | c.772T>C p.F258L | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SLIT1 | c.2021A>T p.N674I | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SNCAIP | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNX13 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- SPATA31A7 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- SPIDR | c.603T>G p.D201E | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- STRA6 | c.430+1G>T p.X144_splice | Splice Site (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- TG | c.5864-2A>C p.X1955_splice | Splice Site (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- TMEM255A | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 133/476 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRIM77 | c.118T>A p.C40S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRIO | c.5619G>A p.M1873I | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TRMT6 | c.1073T>C p.L358S | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBQLN1 | c.1333-1G>T p.X445_splice | Splice Site (SNP) | VAF 43/149 reads (29%) | called by muse, mutect2, varscan2
- UCP1 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 130/514 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP8 | c.2809C>G p.L937V | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZAN | c.5890G>T p.A1964S | Missense Mutation (SNP) | VAF 99/417 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBED9 | c.3615G>T p.W1205C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- ZC3H7A | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.326); called by muse, mutect2
- ZCCHC12 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ZNF281 | c.1488_1497del p.G497Vfs*6 | Frame Shift Del (DEL) | VAF 40/167 reads (24%) | called by mutect2, pindel, varscan2
- ZNF483 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF839 | c.671A>G p.Q224R (on ENST00000558850 / NM_001267827.1; = p.Q340R on NM_018335.5) | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAMTS5 | c.2328C>A p.A776= | Silent (SNP) | VAF 19/231 reads (8%) | catalogued as COSV99537928; called by muse, mutect2
- ANXA6 | c.261G>T p.V87= | Silent (SNP) | VAF 148/498 reads (30%) | called by muse, mutect2, varscan2
- AQP1 | c.513C>T p.A171= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs1164007225; called by muse, mutect2, varscan2
- ARX | c.1156C>A p.R386= | Silent (SNP) | VAF 67/200 reads (34%) | called by muse, mutect2, varscan2
- BCORL1 | c.63C>A p.R21= | Silent (SNP) | VAF 41/199 reads (21%) | called by muse, mutect2, varscan2
- CCR6 | c.27C>T p.S9= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs774953497, COSV59474087; called by muse, mutect2, varscan2
- CCSER1 | c.2241G>C p.V747= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- CDH4 | c.480C>T p.N160= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as rs149210026; called by muse, mutect2, varscan2
- CFHR2 | c.555G>A p.E185= | Silent (SNP) | VAF 43/200 reads (22%) | catalogued as COSV66382017; called by muse, varscan2
- COL5A1 | c.1470C>T p.G490= | Silent (SNP) | VAF 84/240 reads (35%) | called by muse, mutect2, varscan2
- COL9A2 | c.1242C>A p.P414= | Silent (SNP) | VAF 68/250 reads (27%) | called by muse, mutect2, varscan2
- CXCR3 | c.597C>T p.N199= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV101031698, COSV101031751; called by muse, mutect2, varscan2
- DLGAP3 | c.531G>T p.V177= | Silent (SNP) | VAF 102/328 reads (31%) | catalogued as COSV99333203; called by muse, mutect2, varscan2
- GAD2 | c.1308C>A p.S436= | Silent (SNP) | VAF 45/338 reads (13%) | called by muse, mutect2, varscan2
- GALNT17 | c.1131C>A p.A377= | Silent (SNP) | VAF 19/172 reads (11%) | called by muse, varscan2
- HACE1 | c.195A>G p.K65= | Silent (SNP) | VAF 48/241 reads (20%) | called by muse, mutect2, varscan2
- HK3 | c.213G>T p.A71= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as COSV52839694; called by muse, mutect2, varscan2
- KIAA0100 | c.150T>C p.F50= | Silent (SNP) | VAF 77/207 reads (37%) | called by muse, varscan2
- LRP1B | c.3984G>T p.V1328= | Silent (SNP) | VAF 17/202 reads (8%) | catalogued as rs1205183402; called by muse, mutect2
- LVRN | c.2421C>T p.F807= | Silent (SNP) | VAF 26/254 reads (10%) | catalogued as rs760346178, COSV63499151; called by muse, mutect2
- MAPKBP1 | c.882C>T p.F294= (on ENST00000456763 / NM_001128608.2; = p.F288= on NM_014994.3) | Silent (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- MYCL | c.927C>T p.P309= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as rs1487885167; called by muse, mutect2, varscan2
- NBAS | c.5775C>G p.V1925= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- NETO1 | c.144A>C p.A48= | Silent (SNP) | VAF 69/259 reads (27%) | called by muse, mutect2, varscan2
- NTS | c.147A>T p.A49= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1170190883; called by muse, mutect2, varscan2
- OR2T11 | c.393C>A p.V131= | Silent (SNP) | VAF 41/249 reads (16%) | catalogued as COSV100424851; called by muse, mutect2, varscan2
- PCDH8 | c.1659G>T p.S553= | Silent (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- PGM2 | c.1395A>G p.L465= | Silent (SNP) | VAF 31/170 reads (18%) | catalogued as rs759465207; called by muse, mutect2, varscan2
- PLSCR2 | c.474A>T p.R158= (on ENST00000497985 / NM_001199978.1; = p.R85= on NM_020359.2) | Silent (SNP) | VAF 62/191 reads (32%) | called by muse, mutect2, varscan2
- PRPS2 | c.855C>A p.T285= | Silent (SNP) | VAF 47/157 reads (30%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.804A>G p.E268= | Silent (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- REV1 | c.3708C>A p.V1236= | Silent (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- RSPH14 | c.618C>T p.I206= | Silent (SNP) | VAF 110/359 reads (31%) | catalogued as COSV99321032; called by muse, mutect2, varscan2
- SHISA9 | c.675C>A p.T225= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as COSV69636162; called by muse, mutect2, varscan2
- SNTG1 | c.96C>A p.A32= | Silent (SNP) | VAF 59/344 reads (17%) | called by muse, mutect2, varscan2
- SOWAHA | c.1188C>A p.G396= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.1236G>A p.L412= | Silent (SNP) | VAF 112/379 reads (30%) | called by muse, mutect2, varscan2
- SVEP1 | c.1641T>C p.S547= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs1414399551; called by muse, mutect2, varscan2
- TEK | c.1371A>C p.G457= | Silent (SNP) | VAF 96/267 reads (36%) | called by muse, mutect2, varscan2
- TRIM56 | c.1188G>A p.R396= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as rs906177038; called by muse, mutect2, varscan2
- VCX3B | c.33G>A p.P11= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs766878059; called by mutect2, varscan2
- WNT5B | c.465C>T p.D155= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as rs372237487; called by muse, mutect2, varscan2
- ZBTB5 | c.213G>A p.V71= | Silent (SNP) | VAF 72/187 reads (39%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.2997G>T p.A999= | Silent (SNP) | VAF 99/304 reads (33%) | called by muse, mutect2, varscan2
- AC103993.1 | n.150A>C | RNA (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- AC104078.1 | n.227C>G | RNA (SNP) | VAF 95/367 reads (26%) | called by muse, mutect2, varscan2
- ASB18 | c.205+4564C>A | Intron (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- COLGALT2 | c.833-9G>T | Intron (SNP) | VAF 47/150 reads (31%) | catalogued as rs1290539364; called by muse, varscan2
- DENND4B | c.4114+35G>T | Intron (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- DST | c.4297-4533A>G | Intron (SNP) | VAF 35/245 reads (14%) | catalogued as rs1411669153; called by muse, mutect2, varscan2
- FAM71F1 | c.809+1463C>G | Intron (SNP) | VAF 11/187 reads (6%) | called by muse, mutect2
- LINC00602 | n.122C>G | RNA (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2
- LINC00632 | n.56C>A | RNA (SNP) | VAF 47/201 reads (23%) | called by muse, mutect2, varscan2
- LMNB1 | c.*24del | 3'UTR (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- MACROD2 | c.859+796G>A | Intron (SNP) | VAF 18/436 reads (4%) | called by muse, mutect2
- MICAL3 | c.2242-3432C>T | Intron (SNP) | VAF 36/132 reads (27%) | catalogued as rs754173324; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397477 C>T | 3'Flank (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- MST1L | n.676C>T | RNA (SNP) | VAF 22/154 reads (14%) | called by mutect2, varscan2
- NPIPA8 | chr16:18340360 C>T | 5'Flank (SNP) | VAF 50/237 reads (21%) | catalogued as rs199666609; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1913C>T | Intron (SNP) | VAF 46/261 reads (18%) | catalogued as rs535120769; called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65740C>A | Intron (SNP) | VAF 124/435 reads (29%) | called by muse, mutect2, varscan2
- RNASEK | c.196-250del | Intron (DEL) | VAF 104/252 reads (41%) | called by mutect2, pindel*, varscan2*
- RPL13AP20 | n.351G>T | RNA (SNP) | VAF 136/653 reads (21%) | called by mutect2, varscan2
- SAMD3 | c.-21-522C>T | Intron (SNP) | VAF 6/71 reads (8%) | catalogued as rs1232611511; called by muse, mutect2
- TRAPPC9 | c.*51G>T | 3'UTR (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2
- UGT2B27P | n.416A>T | RNA (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- ZNF12 | c.-97C>G | 5'UTR (SNP) | VAF 45/344 reads (13%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451233 C>A | 5'Flank (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- ZNRD2 | chr11:65570474 G>T | 5'Flank (SNP) | VAF 55/162 reads (34%) | called by muse, mutect2, varscan2
